Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7P3, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7P3-01A (Primary Tumor).

[page 1 of 6]
Age [redacted] years Sex: Male

Date Printed:
Date Collected:
Date Received:
Accession No: [redacted]
Physician:
Copy to:

Surgical Pathology Report

Clinical Information

-year-old male with mesothelioma; Pleurectomy, PDT

*CSCE ICD-O-3
Mesothelioma, epithelioid NOS
path 9052/3
Mesothelioma, biphasic
9053/3
Site: Pleura NOS
C38.4*

Final Diagnosis

1. DIAPHRAGM:
Fragments of fibroadipose tissue and striated muscle showing foci of invasive malignant mesothelioma, biphasic type (containing both epithelial and sarcomatoid features). *PW T32, no sarcomatoid features in TCGA specimen. BCK*
2. FISSURE:
Fragments of mesothelial cell lined fibrous tissue showing nodular foci of invasive malignant mesothelioma, biphasic type.
3. LEVEL 9:
A fragment of nodular fibrous tissue showing foci of invasive malignant mesothelioma.
One lymph node, no tumor seen.
4. LEVEL 8:
Fragments of nodular fibrous tissue showing foci of malignant mesothelioma.
One lymph node, no tumor seen.
Adherent benign alveolar lung tissue showing no evidence of invasion.
5. LEVEL 7:
One lymph node, positive for metastatic malignant mesothelioma.
6. LEVEL 6:
A fragment of nodular fibrous tissue showing foci of malignant mesothelioma.
7. LEVEL 5:
One lymph node, no tumor seen.
8. PHRENIC NODE:
Fibroadipose tissue and nodular fibrous tissue showing foci of malignant mesothelioma.
9. ANTERIOR HILAR NODE:
One lymph node, no tumor seen.
Separate fragment of fibroadipose showing detached clusters of atypical mesothelial cells.
10. POSTERIOR HILAR NODE:
Two fragments of mesothelial cell lined fibrous tissue showing foci of malignant mesothelioma.
Tumor appears to focally invade the adherent underlying alveolar lung tissue.

Name: [redacted]
MR: [redacted]

[page 2 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

One lymph node, positive for few cells of metastatic malignant mesothelioma (confirmed by positive CK5/6 immunostain) .

11. ANTERIOR INTERCOSTAL NODE:

Fragments of nodular fibroadipose tissue scant lymphoid tissue showing foci of malignant mesothelioma.

12. ANTERIOR PERICARDIAL TISSUE:

Fragments of benign fibroadipose tissue and striated muscle.

Separate detached fragments of nodular fibrous tissue showing foci of malignant mesothelioma.

13. ANTERIOR HILAR MASS:

Fragments of nodular fibrous tissue showing foci of malignant mesothelioma.

14. ANTERIOR INTERCOSTAL MASS:

One lymph node, positive for metastatic malignant mesothelioma.

Separate fragments of nodular fibrous tissue containing malignant mesothelioma also noted.

15. POSTERIOR INTERCOSTAL NODES:

One lymph node, positive for metastatic malignant mesothelioma (tumor cells are positive for CK5/6 immunostain).

16. RADICAL PLEURECTOMY:

Fragments of fibroadipose tissue showing nodular foci of invasive malignant mesothelioma, biphasic type, see comment.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date

Note

Immunostains are performed with adequate controls on block 16B. Tumor cells are positive for CK5/6, Calretinin and D2-40(both the epithelial and sarcomatoid component). Tumor cells are negative for WT-1 and CD34. Combined histological and immunological features are consistent with malignant mesothelioma, biphasic type.

See disclaimer:

Disclaimer:

The above in-vitro IHC tests may have used reagents labeled for IVD (In Vitro Diagnostic Use), IUO (Investigational Use Only) and/or RUO (Research Use Only) and have not been cleared or approved by the U.S Food and Drug Administration. However, the FDA has determined that such clearance or approval is not necessary for ASR class I tests intended to provide pathologists with adjunctive information to assist their morphologic evaluation. The tests using IUO or IUO reagents were developed and their performance characteristics were validated for diagnostic use by the

Name: [REDACTED]

M: [REDACTED]

[page 3 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected:
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical tests. These Class I ASR tests are not intended to provide diagnostic, prognostic, predictive or therapeutic information that is not directly confirmed by routine histopathologic internal or external control specimens.

Gross Description

The case is received in 16 containers, each labeled with the patient's name and medical record number.

Specimen #1 is received in formalin designated as "Diaphragm" and consists of a 22.7 g, 6.1 x 4.3 x 3.6 cm aggregate of multiple ragged and irregular fragments of tan-pink to tan-white, rubbery, focally friable soft tissue. The largest fragment displays red-brown, rubbery soft tissue, grossly consistent with muscle. One of the smaller fragments displays a 1.5 x 1.4 x 1.2 cm tan-pink, bosselated nodule, which upon sectioning reveals tan-white, friable cut surfaces. Sectioning the remainder of the soft tissue fragments reveals focal areas of tan-white, dense cut surfaces. The nodule is submitted entirely in cassette 1A and representative sections of the remainder of the specimen are submitted in cassettes 1B and 1C.

Specimen #2 is received in formalin designated as "Fissure" and consists of two tan-gray, wrinkled, markedly ragged fragments of soft tissue measuring 8.5 and 9.1 cm in greatest dimension. Each fragment displays multiple tan-pink, bosselated nodules ranging from 0.2 to 1.1 cm in greatest dimension. Sectioning these nodules reveals tan-white, friable cut surfaces. Representative sections are submitted in cassette 2A.

Specimen #3 is received in formalin designated as "Level 9" and consists of two tan-pink, nodular soft tissue fragments measuring 0.8 and 1.7 cm in greatest dimension. The specimen is submitted in toto in cassette 3A.

Specimen #4 is received in formalin designated as "Level 8" and consists of three gray-black to tan-pink, nodular soft tissue fragments measuring 0.8, 0.9 and 1.0 cm in greatest dimension. The largest fragment is bisected and the specimen is submitted entirely in cassette 4A.

Specimen #5 is received in formalin designated as "Level 7" and consists of a 1.3 x 0.9 x 0.3 cm tan-pink, nodular soft tissue fragment. The specimen is bisected and submitted entirely in cassette 5A.

Specimen #6 is received in formalin designated as "Level 6" and consists of a 1.4 x 1.1 x 0.9 cm tan-pink, bosselated soft tissue fragment, which is bisected to reveal tan-pink to tan-white cut surfaces. The specimen is submitted entirely in cassette 6A.

Specimen #7 is received in formalin designated as "Level 5" and consists of a 1.5 x 1.1 x 0.8 cm tan-gray, nodular soft tissue fragment, which is bisected to reveal gray-black to tan-gray, dense cut surfaces. The specimen is submitted entirely in cassette 7A.

Specimen #8 is received in formalin designated as "Phrenic Node" and consists of two gray-black to tan-pink, nodular soft tissue fragments measuring 1.5 and 2.1 cm in greatest dimension. The larger, tan-pink soft tissue fragment has a

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: 4
Physician: Fric
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

bosselated appearance and is bisected to reveal tan-pink to tan-white, focally friable cut surfaces. The larger, bisected soft tissue fragment is submitted entirely in cassette 8A and the smaller, gray-black soft tissue fragment is submitted in toto in cassette 8B.

Specimen #9 is received in formalin designated as "Anterior Hilar Node" and consists of three gray-black to tan-yellow, irregular soft tissue fragments measuring 0.3, 0.4 and 0.8 cm in greatest dimension. The specimen is submitted in toto in cassette 9A.

Specimen #10 is received in formalin designated as "Posterior Hilar Node" and consists of two irregular gray-black soft tissue fragments measuring 0.9 and 3.5 cm in greatest dimension. The specimen is submitted in toto in cassette 10A.

Specimen #11 is received in formalin designated as "Anterior Intercostal Node" and consists of four gray-black, irregular to vaguely nodular soft tissue fragments measuring 0.3, 1.7, 1.7 and 3.0 cm in greatest dimension. The largest fragment is grossly consistent with a fragment of adipose tissue. Sectioning one of the 1.7 cm fragments reveals gray-black to tan-white cut surfaces (cassette 11B). The specimen is submitted entirely in cassettes 11A through 11D, with a single soft tissue fragment in each cassette.

Specimen #12 is received in formalin designated as "Anterior Pericardial Tissue" and consists of a 3.7 x 2.1 x 1.9 cm irregular fragment of tan-yellow, coarsely lobulated, glistening adipose tissue. Sectioning reveals tan-yellow to tan-gray, glistening cut surfaces. Also received in the specimen container is a 2.7 x 2.6 x 1.6 cm fragment of red-brown clotted blood. No discrete masses or lesions are identified. The specimen is submitted entirely in cassettes 12A through 12D.

Specimen #13 is received in formalin designated as "Anterior Hilar Mass" and consists of two irregular to strip-like, ragged fragments of tan-pink to tan-yellow, focally coarsely lobulated, glistening soft tissue measuring 2.4 and 25.2 cm in greatest dimension. The smaller fragment is bosselated and upon sectioning displays tan-white, firm cut surfaces. The larger fragment displays three similar appearing, bosselated nodules measuring 0.3, 0.3 and 0.7 cm in greatest dimension. Sectioning the remainder of the specimen reveals focal tan-white, dense cut surfaces. Representative sections are submitted in cassettes 13A through 13C.

Specimen #14 is received in formalin designated as "Anterior Intercostal Mass" and consists of three irregular and ragged fragments of tan-gray to tan-yellow, focally glistening soft tissue measuring 1.9, 2.4 and 3.3 cm in greatest dimension. Each fragment displays focal tan-pink, nodular, bosselated areas ranging from 1.2 to 1.7 cm in greatest dimension. Sectioning within these areas reveals tan-pink to tan-white, dense, focally friable cut surfaces. Representative sections are submitted in cassette 14A.

Specimen #15 is received in formalin designated as "Posterior Intercostal Nodes" and consists of three tan-yellow, regular, ragged soft tissue fragments measuring 0.3, 0.4 and 0.6 cm in greatest dimension. The specimen is submitted in toto in cassette 15A.

Specimen #16 is received in formalin designated as "Radical Pleurectomy" and consists of a 690 g, 17.0 x 14.5 x 8.8 cm aggregate of multiple ragged and irregular fragments of tan-pink to tan-gray, wrinkled, focally glistening soft tissue, grossly consistent with portions pleura. Each fragment is covered by multiple tan-pink, bosselated, friable nodules ranging from

Name: [REDACTED]
MRN: [REDACTED]

[page 5 of 6]
Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

0.8 to 3.6 cm in greatest dimension. Sectioning within these areas reveals tan-pink to tan-white, friable cut surfaces. The remaining cut surfaces are tan-gray to tan-yellow and glistening. Representative sections are submitted in cassettes 16A through 16F.

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

*Per TSS, dx discrepancy from, sega
specimen is not biphasic, but is
epithelioid only. OK*

Page 5 of 5

Prior Ineligibility History		

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Mesothelioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form		Provide the tumor identifier documented on the initial case quality control form for this case.
Pathologic Diagnosis Provided on Initial Pathology Report	Biphasic mesothelioma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the CQCF	Epithelioid	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	Specimen submitted is epithelioid without sarcomatoid; Clinical frozen specimen reviewed for diagnosis showed both epithelioid & sarcomatoid and diagnosed as biphasic.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.	

Source: NCI Genomic Data Commons file 32f28500-e626-473a-af7c-7a96487cc438 (TCGA-TS-A7P3.6A28A050-677F-4544-9BA2-6825A191CC6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).